Somatic mutation profile of tumor specimen TCGA-X7-A8DC-01A (aliquot TCGA-X7-A8DC-01A-11D-A423-09) from TCGA case TCGA-X7-A8DC, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type AB, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 68.6 years (25,066 days).
Specimen TCGA-X7-A8DC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9a105c6-3ab1-4b5b-9649-ff8d8b37114e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-X7-A8DC-10A (Blood Derived Normal), aliquot TCGA-X7-A8DC-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d4e9693e-f8a9-43e3-bff4-6c48b353f8c9

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 32/530 reads (6%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2
- HECTD1 | c.5989G>C p.V1997L | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as rs1379115787; called by muse, mutect2
- OR2D2 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs767764812, COSV55058262; called by muse, mutect2, varscan2
- XAB2 | c.1435C>T p.R479C | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as rs374573016; called by muse, mutect2, varscan2
- DDX10 | c.1508G>T p.G503V | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SHOC1 | c.2227C>T p.L743= | Silent (SNP) | VAF 12/212 reads (6%) | called by muse, mutect2
